Gene-level copy-number profile of tumor specimen TCGA-CN-5373-01A from TCGA case TCGA-CN-5373, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 55.1 years (20,143 days).
Specimen TCGA-CN-5373-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.4f932b5f-d373-4949-bdfa-c944c3be3504.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-5373-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/18d7cafb-cf56-4c92-b58c-b47c54b7b2fd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 3,801; copy number 2: 51,040; copy number 3: 4,513; copy number 4: 294; copy number 5: 90; copy number 7: 67.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-5373-01A-01D-1432-01): tumor purity 0.47, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–551,657, 9 genes: LINC01986, AC066595.1, CHL1-AS2, AC066595.2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1, AC087428.1.
- chr3:617,789–618,314, 1 gene: RPSAP32.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 157 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:2,717,510–6,015,625, 67 genes, copy number 7 (broad region; genes not listed).
- chr14:21,978,459–22,525,715, 90 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,801. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
